Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JL-01A (Primary Tumor).

1CD-0-3
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 3/11/11
page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – left breast

Unit in charge:

Physician in charge:

Material collected on:

Material received on

Expected time of examination: up to 8 working days

Clinical diagnosis:

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in the neoplastic cell nuclei. No progesterone receptors found in the neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 26 x 19 x 5 cm removed along with axillary tissues sized 10 x 8 x 2 cm and a skin flap of 27 x 11 cm. Tumour sized 2.1 x 2.2 x 0.8 cm on the border of the lower inner quadrants, placed 1.5 cm from the lower edge, 0.1 cm from the base and 2.0 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum NHG3 (3 + 3 + 2: 15 mitoses/10 HPF - visual area of 0.57 mm). Glandular tissue off the tumour showing lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH).

Axillary lymph nodes:

Sinus histiocytosis lymphonodorum (No XI).

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast. (NHG3, pT2, pN0).

Compliance validated b

CONTACT YOUR DOCTOR WITH THIS REPORT!

Case is Ineligible		☒
Reviewed Initial		☒

Source: NCI Genomic Data Commons file 01461646-e769-4f18-a157-40560d7c327d (TCGA-D8-A1JL.156DF753-DB3A-4934-9618-1E18CE46C845.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).